HCMI case HCM-BROD-0204-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0251b915-6bf6-43a3-b3a3-aadbac0be13f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1942; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Classification of tumor: primary; Age at diagnosis: 74.5 years (27,193 days); AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 301 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Nab-paclitaxel; Treatment intent type: Neoadjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant.
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 1,037 days (2.8 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 658.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0204-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0204-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
